Surgical pathology report (de-identified scan), TCGA case TCGA-IG-A3YA, project TCGA-ESCA (Esophageal Carcinoma), tissue source site Asterand, specimen TCGA-IG-A3YA-01A (Primary Tumor).

Path Report: ESOPHAGUS TISSUE CHECKLIST

Specimen type: Excision of tumor

Tumor site: Esophagus - Distal - per TSS

Tumor size: 3 x 3 x 1.2 cm

Histologic type: Squamous cell carcinoma

Histologic grade: Moderately differentiated

Tumor extent: Adventitia

Lymph nodes: 0/4 positive for metastasis (Regional 0/4)

Lymphatic invasion: Not specified

Venous invasion: Not specified

Margins: Uninvolved

Evidence of neo-adjuvant treatment: Not specified

Additional pathologic findings: Not specified

Comments: None

ICD-O-3

Carcinoma, Squamous cell, NOS

807013

Site:

ECF - esophagus, distal third
C15.5

Path - esophagus, NOS
C15.9

6/6/12
RD

Source: NCI Genomic Data Commons file 63e9067d-e252-45ed-bc51-6ec7dcd799d7 (TCGA-IG-A3YA.41B0A7CF-11BD-477C-8315-49985775951B.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).